Gene-level copy-number profile of tumor specimen TCGA-CV-7261-01A from TCGA case TCGA-CV-7261, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 57.5 years (20,992 days).
Specimen TCGA-CV-7261-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.8f695cd3-01dd-4601-8b17-37cf40514422.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7261-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/708faa63-d58d-46a1-b52f-4c4d6d9967d4

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 84; copy number 1: 982; copy number 2: 17,579; copy number 3: 18,926; copy number 4: 16,474; copy number 5: 2,878; copy number 6: 685; copy number 7: 229; copy number 8: 1,523; copy number 9: 306; copy number 10: 26; copy number 11: 48; copy number 17: 74.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7261-01A-11D-2010-01): tumor purity 0.52, ploidy 3.35, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 61 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–20,995,955, 1 gene (within-gene range 0–3): FOCAD.
- chr9:20,999,509–23,438,700, 60 genes (within-gene range 0–3): HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,206 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:131,533,555–132,285,410, 1 gene, copy number 8 (within-gene range 5–8): CPNE4.
- chr3:131,985,855–198,222,513, 1,144 genes, copy number 8 (broad region; genes not listed).
- chr7:126,378,970–142,332,701, 350 genes, copy number 7–10 (broad region; genes not listed).
- chr14:18,333,726–41,904,549, 711 genes, copy number 8–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 982. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
